Surgical pathology report (de-identified scan), TCGA case TCGA-16-1048, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Toronto Western Hospital, specimen TCGA-16-1048-01B (Primary Tumor).

[REDACTED]

Patient Name: [REDACTED]

MRN: [REDACTED]

Gender: M

HCN: [REDACTED]

Ordering MD: [REDACTED]

Service: Surgical Service

Visit #: [REDACTED]

Location: [REDACTED]

Facility: [REDACTED]

Copath #: [REDACTED]

Collected: [REDACTED]

Resulted: [REDACTED]

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. BRN: left frontal brain tumour

DIAGNOSIS

Brain, left frontal lobe: Glioblastoma (WHO grade IV)

[REDACTED]

CLINICAL HISTORY

Brain tumour

GROSS DESCRIPTION

The specimen container, labeled with the patient's name and as "left frontal brain tumour", contains multiple fragments of pink white tissue, received fixed. In aggregate this measures 5.0 x 4.0 cm and weighs 19.0 gm.

1A to 1G - specimen submitted in toto

[REDACTED]

MICROSCOPIC DESCRIPTION

Sections show an infiltrating glial tumour predominantly made up of cells of astrocytic lineage. There is marked nuclear pleomorphism, abundant mitotic activity, microvascular proliferation and numerous areas of necrosis.

Source: NCI Genomic Data Commons file d60ef006-1935-4185-a11b-ed755405d7c3 (TCGA-16-1048.9BA178B7-4D1A-4C60-A3C9-EF55E6719D7D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).